Surgical pathology report (de-identified scan), TCGA case TCGA-G3-A3CH, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Alberta Health Services, specimen TCGA-G3-A3CH-01A (Primary Tumor).

[page 1 of 3]
1C8-0-3

Carcinoma, hepatocellular, NOS 8170/3

Site: Liver C22-0

hw 10/15/11

MRN:

PHN:

ACB:

DOB/Gender:

Telephone:

Encounter:

Location:

Ordering:

Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Specimen Description

A. Liver segment #3

B. Liver segment 4A and 8

Clinical Information

Hepatocellular carcinoma.

Infectious Patient:

Diagnosis

A. Liver Segment # 3:

- Hepatocellular carcinoma, grade II-III with extensive tumor necrosis.
- Venous invasion present.
- Closest margin is 0.5 cm.
- Tumor size: 7.0 x 6.0 x 5.0 cm in maximum dimension.
- Hepatic cirrhosis.
- Chronic hepatitis B (See also).

B: Liver Segment 4A and 8:

- Hepatocellular carcinoma, grade II-III.
- Tumor size: 1.5 x 1.0 x 1.0 cm.
- Lesion comes to within 2.0 mm of blue-painted margin.
- No lymphovascular invasion is seen.

Cc:

Pathology: Provider - Permanent
Page 1 of 3

[page 2 of 3]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

- **Hepatitis B with cirrhosis.**

Gross Description

Received is a single specimen. The requisition and specimen container are labelled with the patient's name
The cassette and AP identifiers are labelled with the Surgical Number

A. The specimen is received fresh and is subsequently placed into formalin. The specimen consists of a segment of liver weighing 223.2 g and measuring 10.0 x 8.0 x 7.0 cm. The surgical resection margin is painted blue. On the liver capsule, there is a roughened hemorrhagic and indurated area measuring 7.0 x 7.0 cm. This area corresponds with a lobulated tan and hemorrhagic mass within the liver parenchyma. This mass measures 7.0 x 5.5 x 6.5 cm. Grossly, the mass comes within 0.5 cm of the blue-painted resection margin. There are also soft necrotic areas noted within the mass. At the edge of the mass, there is a luminal structure filled with the tumor. The tumor within this luminal structure has a yellow/green discoloration. The luminal structure measures approximately 1.5 x 1.0 x 0.7 cm.

Sections of the specimen are as follows:

- A1 and A2 - sections of the luminal structure with tumor.
- A3 and A4 - two sections of tumor in relation to blue-painted resection margin.
- A5 and A6 - two sections of the liver capsule which is rough and hemorrhagic with underlying tumor.
- A7 - section of the tumor involving the liver capsule.
- A8 - section of liver parenchyma uninvolved by tumor.

B. The specimen is received fresh and is subsequently placed into formalin. The specimen consists of an ovoid portion of liver weighing 11.8 g and measuring 4.0 x 3.0 x 2.0 cm. The resection margin is inked blue. The capsule is smooth. Sectioning reveals a tan ovoid lesion which is well circumscribed and measures approximately 1.5 x 1.0 x 1.0 cm. The lesion comes within 0.1 cm to 0.2 cm of the blue-painted margin. The lesion is 0.7 cm away from the liver capsule.

- B1 through B3 - three sections of the lesion closest to the blue-painted resection margin.
- B4 - uninvolved liver parenchyma.

Cc:

[page 3 of 3]
Surgical Pathology Report

Accession Number:

Collected Date:

Pathologist:

Source: NCI Genomic Data Commons file 02ef776a-d5c3-4ca0-8197-6d1e5ac08720 (TCGA-G3-A3CH.735AAE4A-21E1-4481-9D86-385CCE5712D1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).